FM case AD10035 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/7e279625-123f-4102-b6a4-81feebea907f

Female, 62.9 years: Carcinoma, NOS (ICD-O-3 8010/3) of the bladder; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
